Somatic mutation profile of tumor specimen TCGA-5M-AAT5-01A (aliquot TCGA-5M-AAT5-01A-21D-A40P-10) from TCGA case TCGA-5M-AAT5, project TCGA-COAD (Colon Adenocarcinoma).
Specimen TCGA-5M-AAT5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 243ec24f-ccab-4ef2-867a-5d632818213d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5M-AAT5-10A (Blood Derived Normal), aliquot TCGA-5M-AAT5-10A-01D-A40P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f2374c3-0cc7-4c87-b496-5537f86982ad

The open-access MAF lists 78 somatic variants for this specimen: 59 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 18, Nonsense Mutation 7, Frame Shift Ins 1, 3'UTR 1, Splice Region 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 43/101 reads (43%) | catalogued as rs137852216, CM090021, COSV57654256, COSV57668550; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYSF | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 104/272 reads (38%) | catalogued as rs373585652, CM052862; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 55/98 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 70/190 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.644G>A p.S215N | Missense Mutation (SNP) | VAF 63/92 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782177, COSV52679681, COSV52686793, COSV52700292, COSV52891297; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- VWF | c.4022G>A p.R1341Q | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs61749403, CM910403, CM920710, CM961447; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS19 | c.3587G>A p.R1196H | Missense Mutation (SNP) | VAF 76/151 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50810784; called by muse, mutect2, varscan2
- ADGRG4 | c.3938A>G p.H1313R | Missense Mutation (SNP) | VAF 102/435 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.61); catalogued as rs777683726; called by muse, mutect2, varscan2
- APC | c.790C>T p.Q264* | Nonsense Mutation (SNP) | VAF 276/873 reads (32%) | catalogued as CM042289, COSV57339931; called by muse, mutect2, varscan2
- APC | c.4330C>T p.Q1444* | Nonsense Mutation (SNP) | VAF 88/217 reads (41%) | catalogued as CM995166, COSV57337884; called by muse, mutect2, varscan2
- AUP1 | c.43T>C p.S15P | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.736); catalogued as rs1184117944; called by muse, mutect2, varscan2
- CD164 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as COSV51534374; called by muse, mutect2, varscan2
- CD248 | c.2134C>T p.R712C | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as rs747726735, COSV60936393; called by muse, mutect2, varscan2
- CDH22 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs142616480; called by muse, mutect2, varscan2
- CDH23 | c.8785G>A p.V2929M | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs781604742, COSV56473634; called by muse, mutect2, varscan2
- CDH4 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV100848436; called by muse, mutect2
- CFAP100 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 56/92 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367940063; called by muse, mutect2, varscan2
- CYLC2 | c.675G>T p.K225N | Missense Mutation (SNP) | VAF 150/311 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66336918; called by muse, mutect2, varscan2
- DMRTB1 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs767242421, COSV65113279; called by muse, mutect2, varscan2
- DPEP1 | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 35/43 reads (81%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.154); catalogued as rs145664433; called by muse, mutect2, varscan2
- EFHB | c.1084C>T p.R362* | Nonsense Mutation (SNP) | VAF 50/116 reads (43%) | catalogued as rs1238909937, COSV55551232; called by muse, mutect2, varscan2
- F10 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 169/361 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.025); catalogued as rs145282353; called by muse, mutect2, varscan2
- HECW1 | c.3500C>T p.A1167V | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as rs1476570552, COSV67822399; called by muse, mutect2, varscan2
- ITIH5 | c.1315G>A p.G439S | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370636564; called by muse, mutect2, varscan2
- MAGEB6B | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs763403418; called by muse, mutect2, varscan2
- MAPK9 | c.996C>T p.A332= | Splice Region (SNP) | VAF 10/122 reads (8%) | catalogued as rs560961564; called by muse, mutect2
- MAT2B | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147499303; called by muse, mutect2, varscan2
- OR51S1 | c.766C>T p.L256F | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs1395217084; called by muse, mutect2, varscan2
- PAK5 | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 66/100 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as rs753315436; called by muse, mutect2, varscan2
- PLEKHF1 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as rs1044863286, COSV71410355; called by muse, mutect2
- PTPRS | c.4976G>A p.R1659H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs749770933, COSV53619560; called by muse, mutect2, varscan2
- RAPGEF3 | c.1483G>A p.D495N (on ENST00000389212; = p.D453N on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.325); catalogued as rs958000014; called by muse, mutect2, varscan2
- RIN2 | c.1117C>T p.R373W (on ENST00000255006 / NM_001242581.1; = p.R324W on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 277/1089 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.292); catalogued as rs1376170735, COSV54784052, COSV99657639; called by muse, mutect2, varscan2
- SLC4A3 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs548729264; called by muse, mutect2, varscan2
- STK31 | c.2645G>A p.R882Q | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1302905060, COSV63458490; called by muse, mutect2
- TGIF2LX | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 168/387 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.287); catalogued as COSV52215080, COSV52215374, COSV99383415; called by muse, mutect2, varscan2
- TGM4 | c.989C>T p.T330M | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs768242363, COSV56094188; called by muse, mutect2, varscan2
- TUBGCP4 | c.1312C>T p.R438W (on ENST00000260383 / NM_001286414.3; = p.R437W on NM_014444.5) | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs748017076; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZFP36L2 | c.431dup p.G145Rfs*329 | Frame Shift Ins (INS) | VAF 24/69 reads (35%) | catalogued as rs1558428769; called by mutect2, pindel, varscan2
- ABCA4 | c.310A>G p.R104G | Missense Mutation (SNP) | VAF 55/81 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ADGRD1 | c.1821C>A p.N607K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADGRG4 | c.8752G>T p.V2918F | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- ADRA1B | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- ATP13A5 | c.1480G>T p.D494Y | Missense Mutation (SNP) | VAF 197/413 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CACNA1E | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 28/87 reads (32%) | called by muse, mutect2, varscan2
- CNPPD1 | c.992C>G p.T331S | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL5A1 | c.3331G>A p.G1111R | Missense Mutation (SNP) | VAF 76/243 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FHDC1 | c.1979C>A p.S660Y | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.23); called by muse, mutect2
- FUT3 | c.76G>C p.V26L | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GRM1 | c.2036C>A p.T679N | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- LRRC23 | c.682C>T p.H228Y | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- MEPCE | c.739del p.E247Rfs*4 | Frame Shift Del (DEL) | VAF 7/69 reads (10%) | called by mutect2, pindel, varscan2
- PES1 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- SLC22A13 | c.804C>A p.F268L | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TAF1L | c.3502G>T p.V1168F | Missense Mutation (SNP) | VAF 119/270 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TMEM266 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- VCPIP1 | c.260_262del p.E87del | In Frame Del (DEL) | VAF 37/149 reads (25%) | called by pindel, varscan2
- ZNF280D | c.2680G>T p.D894Y | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ZNF696 | c.472T>G p.C158G | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCC4 | c.1989A>G p.Q663= | Silent (SNP) | VAF 75/198 reads (38%) | catalogued as rs775937284; called by muse, mutect2, varscan2
- ARHGAP21 | c.5307A>G p.L1769= | Silent (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- CLASP1 | c.1170C>A p.I390= | Silent (SNP) | VAF 118/258 reads (46%) | called by muse, mutect2, varscan2
- COL4A5 | c.2604C>T p.P868= | Silent (SNP) | VAF 117/326 reads (36%) | catalogued as rs781337825, COSV100088361; called by muse, mutect2, varscan2
- CSRP2 | c.228C>T p.G76= | Silent (SNP) | VAF 30/75 reads (40%) | called by muse, mutect2, varscan2
- DMXL2 | c.2550T>G p.L850= | Silent (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- FAM83H | c.1269C>T p.F423= | Silent (SNP) | VAF 324/890 reads (36%) | called by muse, mutect2, varscan2
- FRMD3 | c.612A>T p.P204= | Silent (SNP) | VAF 47/97 reads (48%) | called by muse, mutect2, varscan2
- FRMPD3 | c.3777C>T p.T1259= | Silent (SNP) | VAF 54/414 reads (13%) | called by muse, mutect2, varscan2
- GPRIN1 | c.924G>A p.A308= | Silent (SNP) | VAF 38/123 reads (31%) | catalogued as rs748837601; called by muse, mutect2, varscan2
- HRNR | c.5640G>A p.Q1880= | Silent (SNP) | VAF 38/438 reads (9%) | called by muse, mutect2
- LSS | c.507C>T p.D169= | Silent (SNP) | VAF 58/82 reads (71%) | catalogued as rs757467514, COSV100710882; called by muse, mutect2, varscan2
- PRR35 | c.1134C>T p.G378= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as rs1315404847, COSV53462438; called by muse, mutect2, varscan2
- PTGIS | c.1077C>T p.R359= | Silent (SNP) | VAF 27/119 reads (23%) | catalogued as rs757932077; called by muse, mutect2, varscan2
- SARDH | c.798C>T p.C266= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as rs1289630771, COSV53835176; called by muse, mutect2, varscan2
- SLC16A14 | c.549C>T p.C183= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as COSV54620749; called by muse, mutect2, varscan2
- TIAM1 | c.660G>A p.P220= | Silent (SNP) | VAF 41/54 reads (76%) | catalogued as rs374794029, COSV54556716; called by muse, mutect2, varscan2
- ZFPM2 | c.45G>A p.P15= | Silent (SNP) | VAF 49/106 reads (46%) | catalogued as rs1442044896, COSV101343524, COSV68274572; called by muse, mutect2, varscan2
- FYTTD1 | c.*1G>A | 3'UTR (SNP) | VAF 51/375 reads (14%) | called by muse, mutect2, varscan2
